Gene-level copy-number profile of tumor specimen TCGA-02-0440-01A from TCGA case TCGA-02-0440, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.8 years (22,955 days).
Specimen TCGA-02-0440-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.7ff95a93-21ca-478f-a5ca-5b2326b00e64.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 4,999 have no estimate.
https://portal.gdc.cancer.gov/files/2c849049-184e-4ea5-bbf8-e23fc100fa8e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 4,462; copy number 2: 48,146; copy number 3: 2,985; copy number 5: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0440-01): tumor purity 0.88, ploidy 1.96, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–24,088,051, 25 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1.
- chr9:26,066,675–26,118,408, 1 gene: AL353753.1.
- chr9:26,746,953–26,786,874, 1 gene (within-gene range 0–1): AL451137.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:53,377,641–53,460,862, 1 gene, copy number 5 (within-gene range 2–5): FIP1L1.
- chr4:53,459,301–53,701,405, 3 genes, copy number 5 (within-gene range 2–5): LNX1, LNX1-AS1, AC095040.1.

Autosomal genes at a single copy (total copy number 1): 4,462. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
